Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CX, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CX-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Department of Pathology,

DOB:
Physician:

Sex: F

Collector

Received:

Case type: Surgical Case

Accession:

DIAGNOSIS

- (A) NODULE RIGHT UPPER POLE:
Thymic tissue, no tumor present

- (B) TOTAL THYROIDECTOMY:
PAPILLARY THYROID CARCINOMA, RIGHT LOBE (3.3 CM)
Extrathyroidal extension is not identified
LYMPHOVASCULAR INVASION IS PRESENT
Resection margins are free of tumor

1CD-0-3
carcinoma, papillary, thyroid, 8260/3
Site: thyroid, nos C73.9

hw
10/15/11

- (C) RULE OUT RIGHT INFERIOR PARATHYROID:
No tumor present in one lymph node (0/1)
Parathyroid gland is not identified

- (D) RIGHT PARATRACHEAL AND MEDIASTINAL LYMPH NODES:
No tumor present in twelve lymph nodes (0/12)
Thymic tissue, no tumor present

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) NODULE RIGHT UPPER LOBE - A tan-red, irregular fragment of soft tissue (0.5 x 0.4 x 0.3 cm). The specimen is bisected and entirely submitted for frozen section in A.

*FS/DX: BENIGN LYMPHOID TISSUE.

(B) TOTAL THYROIDECTOMY - A product of total thyroidectomy (5.0 x 3.5 x 3 cm) contains a well-circumscribed nodule (3.3 x 3.3 x 2.0 cm) in the right lobe. Left lobe is grossly unremarkable.

SECTION CODE: Submitted entirely under B1-B9, Sequential sectioning of the right lobe from superior to inferior; B10, representative section of the isthmus; B11-B14, sequential sectioning of the left lobe from superior to inferior.

(C) RULE OUT RIGHT INFERIOR PARATHYROID - A tan soft tissue fragment (0.2 x 0.1 x 0.1 cm). Touch prep is made and the specimen is entirely frozen in C.

*FS/DX: BENIGN LYMPH NODE.

(D) RIGHT PARATRACHEAL MEDIASTINAL LYMPH NODE - A fragment of fibrofatty tissue measures 4.5 x 1.5 x 0.8 cm. Multiple lymph nodes ranging from 0.3 x 0.3 x 0.3 cm to 0.8 x 0.5 x 0.3 cm are identified.

SECTION CODE: D1, five lymph nodes; D2, five lymph nodes; D3, three lymph nodes.

CLINICAL HISTORY

Papillary thyroid cancer.

[page 2 of 2]
Surgical Pathology Report

Department of Pathology

DOB:
Physician:

Sex: F

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by
approved by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or

Released by:

Surgical Pathology Report		Page 2 of 2
File under: Pathology		

Source: NCI Genomic Data Commons file a8ad8812-574e-47c8-9db3-1fe2c7820d87 (TCGA-EL-A3CX.DF9BD55E-DBE5-4644-B7AD-FEC3B77B2649.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).